Surgical pathology report (de-identified scan), TCGA case TCGA-WE-A8K5, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-A8K5-06A (Metastatic).

[page 1 of 4]
Clinician

Status

(Plastic Surgery)

F

Sample

(Tissue) Collected

Received

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT: Plastic Surgery

HISTOPATHOLOGY REPORT

LAB No:

ICD-O-3
Melanoma, lentigo maligna
8742/3
Site: Right thigh, subcutaneous
tissue 049.2
JPD 11/22/13

CASE HISTORY:

Excision biopsy from left leg melanoma. Marker 12 o'clock.
Separate sample in pot. Short saphenous vein.

MACROSCOPIC:

Skin ellipse 3.5 x 3cm with a stitch inserted at one edge. Surface appears slightly nodular, on which appears 0.5cm nodule and another one towards the other edge 0.6cm. Cut coloured irregular pigmentation in the neighbourhood of the first nodule, is also seen. 12 to 6'o'clock through both nodules in A, 12'o'clock blue, 6'o'clock green, 3'o'clock red and 9'o'clock orange. 3'o'clock margin in B and 9'o'clock margin in C.

Additional description

Separate fragment of fatty/vascular tissue 2 x 1 x 0.5cm is present.

MICROSCOPY:

Skin shows a regressing melanocytic lesion which represents a malignant melanoma, which is difficult to type but probably lentigo maligna type.

TUMOUR TYPE:Malignant melanoma, difficult to type

GROWTH PHASE:verical

BRESLOW THICKNESS:1.7mm

CLARK LEVEL:3

ULCERATION:Not seen

LYMPHOVASCULAR INVASION:Not seen

PERINEURAL INVASION:Not seen

REGRESSION:Present

MICROSATELLITES:Not seen

CO-EXISTENT NAEVUS:Not seen

MITOTIC RATE:Up to 12 per square mm

TUMOUR INFILTRATING LYMPHOCYTES:Present, not brisk

COMPLETELY EXCISED:Yes

EXCISION MARGINS:

Deep:4mm

Peripheral:7mm

STAGE:pT2a

A separate fragment of underlying muscular tissue shows no evidence of malignancy.

[page 2 of 4]
REPORTED BY: _____, Consultant Histopathologist
Copy of Report to Cancer Registry

Sample	(Tissue) Collected	Received
--------	--------------------	----------

1&2. SENTINEL LYMPH NODE 1&2 FROM LEFT GROIN: NO EVIDENCE OF METASTATIC MALIGNANT MELANOMA.

[page 3 of 4]
3. WIDER EXCISION OF MELANOMA, MALIGNANT LEFT ANKLE: MULTIFOCAL
BASAL CELL CARCINOMA, FOREIGN BODY GRANULOMATOUS REACTION IN
GRANULATION TISSUE

REPORTED BY:

, Consultant Histopathologist
Copy of Report to Cancer Registry

REPORT DATE:

Sample (Fine Needle Aspirate) Collected
Received

Non Gynae Fine Needle Aspirate

Non Gynae Fine Needle Aspirate

ADDRESS FOR REPORT: Plastic Surgery
Report to Cancer Registry

CYTOPATHOLOGY REPORT

LAB No:

CASE HISTORY:

Melanoma left leg. Nodule adjacent to sentinal node scar.

MACROSCOPIC:

2 air-dried slides dated

MICROSCOPY:

A highly cellular sample composed of dyscohesive plasmacytoid cells with round to oval nuclei and moderate amounts of cytoplasm. Cellular pleomorphism, double mirror image nuclei and focal intracytoplasmic pigment is seen. The appearances are consistent with metastatic malignant melanoma.

DIAGNOSIS:

FNA (LEFT THIGH): METASTATIC MALIGNANT MELANOMA

REPORTED BY:

, Histopathology
, Consultant Histopathologist

REPORT DATE:

Sample (Tissue) Collected Received

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT: PLASTIC SURGERY
Copy To: Cancer Registry

[page 4 of 4]
**SUPPLEMENTARY REPORT
LAB No:

Previous left calf malignant melanoma. CT scan: Brain metastases. Lung metastases, spleen metastases are also seen.

Nodular fragment 1.5cm.

Metastatic malignant melanoma is confirmed. BRAF immunostain is negative. Molecular genetic testing to follow

LEFT THIGH TISSUE: METASTATIC MALIGNANT MELANOMA

, Consultant Histopathologist.

REPORT DATE:

The case was sent to _____ for BRAF testing. _____ reports

Real time PCR analysis of the BRAF gene has revealed the presence of a mutation within codon 600 of the BRAF gene.

technique does not differentiate between V600E and V600K.

MELANOMA: PATHOGENIC MUTATION WITHIN CODON 600 OF BRAF.

, Consultant Histopathologist

Source: NCI Genomic Data Commons file cd10e1b4-b6c8-429d-9f8b-c62686a93173 (TCGA-WE-A8K5.144B09EE-F6F6-4151-A20C-BD2B9243C61F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).